Somatic mutation profile of tumor specimen 0DRKKL from CCDI case PBCGGS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.2 years (3,350 days).
Specimen 0DRKKL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ea6e32f-7550-4efd-a9df-f57687084c08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRKKU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de7a477a-e5f6-4661-b7b2-9be25dfa02b5

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, 3'UTR 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 216/521 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 492/827 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MED12 | c.2641G>C p.E881Q | Missense Mutation (SNP) | VAF 348/1001 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61338670; called by muse, mutect2, varscan2
- DDR2 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 26/929 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZBED4 | c.1787G>A p.G596D | Missense Mutation (SNP) | VAF 273/658 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC3H12B | c.23A>T p.E8V | Missense Mutation (SNP) | VAF 24/714 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2
- MAPK8IP2 | c.2181C>T p.L727= | Silent (SNP) | VAF 50/878 reads (6%) | catalogued as rs565845545; called by muse, mutect2
- TAS1R2 | c.324C>A p.V108= | Silent (SNP) | VAF 180/460 reads (39%) | catalogued as rs1297411177; called by muse, mutect2, varscan2
- TMC2 | c.1273C>T p.L425= | Silent (SNP) | VAF 26/966 reads (3%) | called by muse, mutect2
- C16orf96 | c.*19C>G | 3'UTR (SNP) | VAF 164/382 reads (43%) | called by muse, mutect2, varscan2
- CACNA1H | c.*749G>A | 3'UTR (SNP) | VAF 26/152 reads (17%) | catalogued as rs368488309; called by mutect2, varscan2
- MIA2 | c.1955-87G>A | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- RTL1 | c.*76C>A | 3'UTR (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
